CCDI case PBBPPC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas.
https://portal.gdc.cancer.gov/cases/5449d294-d495-4cd4-b3df-aad1345a364d

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 12.7 years (4,656 days).

Biospecimens (3 samples)
- Sample 0DEA0N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEA0Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEA0W: Tissue type: Tumor; Specimen type: Solid Tissue.
